Somatic mutation profile of tumor specimen C3L-00807-54 (aliquot CPT0262160002) from CPTAC case C3L-00807, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 57.7 years (21,058 days).
Specimen C3L-00807-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a479a4fd-e909-47ca-b5f1-20255e8c1dee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00807-50 (Buccal Cell Normal), aliquot CPT0262150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a0f124b-aa0a-476b-9ea2-325cfd009792

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNA2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs891946949; called by muse, mutect2
- FLNA | c.7354G>A p.V2452M (on ENST00000369850 / NM_001110556.2; = p.V2444M on NM_001456.3) | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs782450850, COSV100774869; called by muse, mutect2, varscan2
- AHI1 | c.619A>T p.K207* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2
- BSN | c.8266G>T p.G2756C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KMT2C | c.14047dup p.A4683Gfs*3 | Frame Shift Ins (INS) | VAF 59/126 reads (47%) | called by mutect2, varscan2
- MMP20 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 155/406 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PKHD1L1 | c.9409C>A p.Q3137K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPRN | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, varscan2
- ADAM15 | c.624G>A p.V208= | Silent (SNP) | VAF 108/299 reads (36%) | called by muse, mutect2, varscan2
- FLG | c.6324G>A p.A2108= | Silent (SNP) | VAF 29/421 reads (7%) | catalogued as rs763227797; called by muse, mutect2
- ITPRIP | c.1617C>A p.P539= | Silent (SNP) | VAF 38/98 reads (39%) | called by mutect2, varscan2
- MCTP2 | c.258G>T p.G86= | Silent (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- ZBTB7C | c.459C>T p.D153= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs567201769, COSV59688326, COSV59689095; called by muse, mutect2, varscan2
- MYPN | chr10:68109440 G>A | 5'Flank (SNP) | VAF 30/60 reads (50%) | catalogued as rs1394253520; called by muse, varscan2
- TUBBP5 | n.1007C>T | RNA (SNP) | VAF 72/198 reads (36%) | catalogued as rs1397428790; called by muse, varscan2
